CCDI case PBBPSJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2dc561f5-9b9c-406b-93d5-47311e47a313

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.8 years (2,126 days).

Biospecimens (3 samples)
- Sample 0DEHN0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHQ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DEHQ8: Tissue type: Tumor; Specimen type: Solid Tissue.
